CCDI case PBCEGP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/711d0b29-5ac7-49b0-9931-7dc965527bdf

Demographics
Sex at birth: male.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,951 days).

Biospecimens (3 samples)
- Sample 0DQ55C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ55P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ55T: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
